Somatic mutation profile of tumor specimen BA2813D (aliquot aq-BA2813D) from BEATAML1.0 case 2206, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.2 years (23,431 days).
Specimen BA2813D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dd8bc4b-5a84-4404-88a3-c6d08837e876.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2938D (Solid Tissue Normal), aliquot aq-BA2938D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e014e7ee-bf4b-43c6-ba56-269ae24c871f

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- CYP4B1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs748528353, COSV54726132; called by muse, varscan2
- CENPK | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL11A1 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PITPNM3 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); called by muse, mutect2
- ZBTB21 | c.548del p.K183Rfs*13 | Frame Shift Del (DEL) | VAF 31/140 reads (22%) | called by mutect2, pindel, varscan2
- ZNF106 | c.2029G>T p.A677S | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2
- HES6 | c.363C>T p.V121= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as rs1383408436; called by muse, varscan2
- PITPNA | c.69G>T p.L23= | Silent (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- ZBTB12 | c.678T>A p.P226= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- HNF4A | c.-15G>A | 5'UTR (SNP) | VAF 46/109 reads (42%) | catalogued as rs568730599; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RNF150 | c.1198+10G>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
